Surgical pathology report (de-identified scan), TCGA case TCGA-DU-A6S7, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Henry Ford Hospital, specimen TCGA-DU-A6S7-01A (Primary Tumor).

[page 1 of 4]
Surgical Pathology Report

Patient Name: Phone #: Accession #:
Med. Rec. #: Client: Taken:
DOB: (Age:) Location: Received:
Gender: F Acct: Reported:
Physician(s):
Phy Location:

Clinical History

Brain tumor.

Operative Diagnoses

Operation / Specimen

A: Brain, left frontal, craniotomy

Pathologic Diagnosis

A. Brain, left frontal, craniotomy:

1. Anaplastic astrocytoma, WHO grade 3
2. Negative for co-deletion of chromosomal arms 1p and 19q
3. Positive for IDH1-R132S mutation
4. Ki-67/ MIB1 proliferation index: up to approximately 10%

See comment.

Comment

The diffuse astrocytoma has an area with up to 4 mitoses in 10 high power fields. There is no definite microvascular proliferation and no tumor necrosis identified in the initial and deeper sections. The immunostain for the mutant IDH1-R132H protein is negative. A point mutation is detected in *IDH1* by DNA sequencing (see attached report).

Overall, this diffuse glioma is consistent with anaplastic astrocytoma, WHO grade 3.

Electronically Signed Out

Consultant:

Senior Staff Pathologist
Senior Staff Pathologist

Procedures/Addenda

Loss of Heterozygosity 1p, 19q Assay (LOH)

Date Ordered: Date Reported:

Interpretation

NEGATIVE: Allelic loss on chromosome arm 1p and chromosome arm 19q is NOT detected.

Surgical Pathology

Page 2 of 4

Informative loci are: D1S548, D1S1592, D1S552, D19S219, D19S606, and D19S1182

Results-Comments

Testing performed on DNA extracted from tumor paraffin block (A2). DNA extracted from a

corresponding blood specimen was used as a normal reference control.

H and E slide was examined and tumor DNA was enriched by microdissection

TEST DESCRIPTION: Allelic loss is assessed by PCR assay in Normal DNA (baseline)/ Tumor DNA pairs using 3

markers at both 1p and 19q. The 3 markers on 1p are D1S548, D1S1592, and D1S552 (with D1S468, D1S1612, and

D1S496 as backup markers) and the 3 markers on 19q are D19S219, D19S412, and PLA2G4C (with D19S606 and

ICD-0-3
GSCF Astrocytoma, grade III 9401/3
path Astrocytoma, anaplastic 9401/3
Site: Brain, supratentorial NOS 071.0
JW 7/24/13

[page 2 of 4]
D19S1182 as backup). All markers are microsatellites (2 or 4 nt repeats) except PLA2G4C which is a minisatellite (26 nt repeat) polymorphism. The markers were selected based on heterozygosity score, amplicon size, and ease of interpretation. The backup markers are used if the first line markers at that chromosome arm are uninformative or otherwise ambiguous in their interpretation. LOH at all informative loci on each chromosomal arm represents the typical finding in oligodendrogliomas with 1p and 19q deletion.
FDA COMMENT: The above data are not to be construed as the results from a stand-alone diagnostic test. This test was developed and its performance characteristics determined by the as required by CLIA '88 regulations. It has not been cleared or approved for specific uses by the U.S. Food and Drug Administration (FDA). The FDA has determined that such clearance or approval is not necessary. These results are provided for informational purposes only, and should be interpreted only in the context of established procedures and/or diagnostic criteria.
TECHNICAL SENSITIVITY: The presence of >15% non-neoplastic cells in the sample may preclude the detection of allelic loss.

Electronically Signed Out

Senior Staff Pathologist

IDH1 Mutation Detection Assay

Date Ordered:

Date Reported:

Interpretation

POSITIVE - There is evidence of IDH1 point mutation as indicated by the nucleotide change in codon 132

compared to the electropherogram of the reference normal sample (wild type).

The amino acid substitution is p.Arg132Ser

Results-Comments

TEST DESCRIPTION: IDH1/2 Mutation Analysis

Test performed on DNA extracted from tumor paraffin block

-A1

H and E slide was examined and no microdissection was needed.

Mutation of IDH1 occurs early in glioma progression with somatic mutations of the R132 residue of IDH1 identified in

majority (>70%) of grades II and III astrocytomas and oligodendrogliomas, as well as in secondary GBMs that

developed from these lower grade lesions. Mutation analysis of closely related IDH2 revealed mutations of IDH2

residue R172, with most mutations occurring in tumors lacking IDH1 mutations. Tumors with IDH1 or IDH2 mutations

have distinctive genetic and clinical characteristics, and patients with such tumors have a better outcome than those

with wild type IDH genes.

Surgical Pathology

Page 3 of 4

Mutations in IDH1/2 are detected by DNA sequencing procedures. The limit of detection of standard bidirectional sequencing is approximately 20-25%. In order to increase assay sensitivity tumor enrichment must be performed by

manual microdissection when tumor cells in the block constitute less than 50% of nucleated cells.

FDA COMMENT: The above data are not to be construed as the results from a stand alone diagnostic test. This test

[page 3 of 4]
was developed and its performance characteristics determined by the

as required by CLIA '88 regulations. It has not been cleared or approved for specific uses by the US Food and Drug Administration (FDA). The FDA has determined that such clearance or approval is not necessary. These results are provided for informational purposes only, and should be interpreted only in the context of established procedures and/or diagnostic criteria.

Electronically Signed Out

Senior Staff Pathologist

IDH2 Mutation Detection Assay

Date Ordered:

Date Reported:

Interpretation

NEGATIVE - There is no evidence of IDH2 point mutation, as indicated by the absence of any nucleotide changes in codon 172 of the IDH2 gene compared to the electropherogram of the reference normal sample (wild type).

Results-Comments

TEST DESCRIPTION: IDH2 Mutation Analysis

Test performed on DNA extracted from tumor paraffin block

-A1

H and E slide was examined and no microdissection was needed.

Mutation of IDH1 occurs early in glioma progression with somatic mutations of the R132 residue of IDH1 identified in

majority (>70%) of grades II and III astrocytomas and oligodendrogliomas, as well as in secondary GBMs that

developed from these lower grade lesions. Mutation analysis of closely related IDH2 revealed mutations of IDH2

residue R172, with most mutations occurring in tumors lacking IDH1 mutations. Tumors with IDH1 or IDH2 mutations

have distinctive genetic and clinical characteristics, and patients with such tumors have a better outcome than those

with wild type IDH genes.

Mutations in IDH1/2 are detected by DNA sequencing procedures. The limit of detection of standard bidirectional

sequencing is approximately 20-25%. In order to increase assay sensitivity tumor enrichment must be performed by

manual microdissection when tumor cells in the block constitute less than 50% of nucleated cells.

FDA COMMENT: The above data are not to be construed as the results from a stand alone diagnostic test. This test

was developed and its performance characteristics determined by the

as required by CLIA '88 regulations. It has not been cleared or approved for specific uses by the US Food and Drug Administration (FDA). The FDA has determined that such clearance or approval is not necessary. These results are provided for informational purposes only, and should be interpreted only in the context of established procedures and/or diagnostic criteria.

Electronically Signed Out

Senior Staff Pathologist

Intra-Operative Consultation

A. Brain tumor, excision biopsy: Gliofibrillary neoplasm, consistent with diffuse glioma.

Cytological smears are performed at the

and the results are reported to the

Physician of Record

[page 4 of 4]
Surgical Pathology

Page 4 of 4

Senior

Staff Pathologist

Gross Description

A. Brain, left frontal, craniotomy:

FIXATIVE: None

GENERAL: A 1.4 x 1.2 x 0.5 cm aggregate of grey-tan to dusky soft tissue, submitted for intraoperative evaluation.

SECTIONS: Entirely submitted in A1 - A2.

ICD-9(s): 191.1 191.1

Billing Fee Code(s):

Histo Data

Part A: Brain, left frontal, craniotomy

Taken:

Received:

Stain/cnt Block Ordered Comment

H&E x 1 1

IDH1-sld x 1 1

IDH1-sld x 1 1

no trim please

IDH2-sld x 1 1

MIB1-DA x 1 1

Rct 1 H&E x 1 1

no trim please

Rct 2 H&E x 1 1

TPS H&E x 1 1

H&E x 1 2

LOH-sld x 1 2

Rct 1 H&E x 1 2

Rct 2 H&E x 1 2

PAA Discrepancy		

Source: NCI Genomic Data Commons file cad6d436-bcba-45f9-a0c8-2b0dd9ffdb5c (TCGA-DU-A6S7.7FA0F0F7-F7B8-4127-988E-C3A43496CCCA.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).